TCGA case TCGA-06-0686 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c931f3bd-74c5-4ebd-bc0f-c7c6becd25ab

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Dead; Days to death: 432 days (1.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 53.4 years (19,503 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Banoxantrone; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 66 days; Number of cycles: 1; Treatment dose: 1,876 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Banoxantrone; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 60 days; Number of cycles: 1; Treatment dose: 1,875 mg; Prescribed dose: 750; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 66 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 66 days; Number of cycles: 1; Treatment dose: 185 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 95 days; Days to treatment end: 127 days; Number of cycles: 2; Treatment dose: 380 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Gossypol; Initial disease status: Progressive Disease; Days to treatment start: 175 days; Days to treatment end: 279 days; Number of cycles: 4; Treatment dose: 20 mg; Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib; Initial disease status: Progressive Disease; Days to treatment start: 309 days; Days to treatment end: 370 days (1.0 years); Number of cycles: 2; Treatment dose: 150 mg/day; Prescribed dose: 150; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 384 days (1.1 years); Days to treatment end: 412 days (1.1 years); Number of cycles: 2; Treatment dose: 312 mg; Prescribed dose: 125; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 412 days (1.1 years); Days to treatment end: 412 days (1.1 years); Number of cycles: 1; Treatment dose: 1,182 mg; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 53.8 years (19,663 days); Days to diagnosis: 160 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 160 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 160 (post initial treatment): Progression or recurrence: Yes; Days to progression: 160 days.
- Days to follow up: 286 days; Disease response: With Tumor.
- Days to follow up: 432 days (1.2 years); Disease response: With Tumor.
- Karnofsky performance status: 90; Timepoint: Post Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-06-0686-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 95; Percent normal cells: 20; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-06-0686-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 90; Percent normal cells: 30; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-06-0686-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0686-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Preoperative.
- Drug treatment 1: Regimen number: 01.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 01; Pharmaceutical therapy drug name: A4QN.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 03; Pharmaceutical therapy drug name: Erlotinib (Tarceva).
- Drug treatment 5: Regimen number: 02; Pharmaceutical therapy drug name: AT 101.
- Drug treatment 6: Regimen number: 04.
- Drug treatment 8: Regimen number: 04; Pharmaceutical therapy drug name: Irintotecan.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 432 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 432 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 160 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0686-01A-01D-0333-01): tumor purity 0.85, ploidy 2.06, whole-genome doublings 0.
